CCDI case PBCGXV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/5fd99e4e-54c0-4b5b-9afb-76af23361123

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.8 years (7,233 days).

Biospecimens (2 samples)
- Sample 0DRQSO: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRQT0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
